Somatic mutation profile of tumor specimen MMRF_2531_2_BM_CD138pos (aliquot MMRF_2531_2_BM_CD138pos_T1_KHS5U_L16523) from MMRF case MMRF_2531, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.5 years (25,765 days).
Specimen MMRF_2531_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b844561c-428c-4366-981e-37596d3744f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2531_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_2531_1_PB_CD3pos_C5_KHS5U_K15148; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f68a373a-ad30-4db1-b9ba-ada497eeac30

The open-access MAF lists 137 somatic variants for this specimen: 51 protein-altering or splice-affecting, 13 silent, 73 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 45, Missense Mutation 40, Intron 15, Silent 13, 5'UTR 7, RNA 4, Nonsense Mutation 4, Splice Site 3, Frame Shift Del 3, 5'Flank 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.646G>C p.V216L | Missense Mutation (SNP) | VAF 70/70 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs730882025, CM159291, CX952222, COSV52671096, COSV52751864, COSV53384298; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC11 | c.740T>C p.I247T | Missense Mutation (SNP) | VAF 49/88 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0.102); catalogued as rs1189976702; called by muse, mutect2, varscan2
- AKAP17A | c.1243C>T p.R415W | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1204041488; called by muse, mutect2, varscan2
- AKR1B10 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 68/125 reads (54%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.643); catalogued as rs769711685; called by muse, mutect2, varscan2
- AL645922.1 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 47/89 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs547881286, COSV54963054; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATL3 | c.997C>T p.Q333* | Nonsense Mutation (SNP) | VAF 24/113 reads (21%) | catalogued as rs767260184; called by muse, mutect2, varscan2
- ATM | c.5059G>C p.A1687P | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV104377434; called by muse, mutect2, varscan2
- CASP4 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.022); catalogued as rs147548594, COSV67744743; called by muse, mutect2, varscan2
- CIC | c.1745C>T p.A582V | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs200040001; called by muse, mutect2, varscan2
- DSG4 | c.1743G>A p.M581I | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV57388871; called by muse, mutect2
- IGHJ4 | c.34A>C p.T12P | Missense Mutation (SNP) | VAF 36/36 reads (100%) | PolyPhen benign (0.022); catalogued as rs374291610; called by muse, varscan2
- IGKJ4 | c.20C>G p.T7S | Missense Mutation (SNP) | VAF 44/44 reads (100%) | PolyPhen benign (0.055); catalogued as rs139402168; called by muse, varscan2
- IGLV3-1 | c.203A>C p.Q68P | Missense Mutation (SNP) | VAF 85/85 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs373323725; called by muse, mutect2, varscan2
- INTS1 | c.3829G>A p.E1277K | Missense Mutation (SNP) | VAF 122/231 reads (53%) | SIFT tolerated (0.37); PolyPhen benign (0.035); catalogued as rs1343068610; called by muse, mutect2, varscan2
- KRTAP13-4 | c.266C>A p.S89Y | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61878454; called by muse, mutect2, varscan2
- KYNU | c.1080A>T p.K360N | Missense Mutation (SNP) | VAF 76/158 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51580158; called by muse, mutect2, varscan2
- LRRC72 | c.65A>C p.E22A | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as rs1357337462; called by muse, mutect2, varscan2
- LRRC8B | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 69/140 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0.051); catalogued as COSV58376910; called by muse, mutect2, varscan2
- OLA1 | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 9/17 reads (53%) | catalogued as COSV52974073; called by muse, varscan2
- PCDH17 | c.1223del p.G408Vfs*18 | Frame Shift Del (DEL) | VAF 15/81 reads (19%) | catalogued as COSV64974164; called by mutect2, pindel, varscan2
- PSMC6 | c.241del p.E81Kfs*26 (on ENST00000612399; = p.E67Kfs*26 on NM_002806.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 29/55 reads (53%) | catalogued as COSV71629412; called by mutect2, pindel, varscan2
- RHOBTB3 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 73/142 reads (51%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.453); catalogued as rs768905935, COSV66102659; called by muse, mutect2, varscan2
- TRRAP | c.9511C>T p.R3171W (on ENST00000359863 / NM_001244580.1; = p.R3142W on NM_003496.3) | Missense Mutation (SNP) | VAF 54/89 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs778465879, COSV62838500; called by muse, mutect2, varscan2
- TUT7 | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 15/224 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs763582765; called by muse, mutect2
- ZNF165 | c.1250G>A p.R417K | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as COSV66103120; called by muse, mutect2, varscan2
- A2M | c.599A>T p.Q200L | Missense Mutation (SNP) | VAF 49/85 reads (58%) | SIFT tolerated (0.95); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ACE | c.3279C>T p.L1093= | Splice Region (SNP) | VAF 67/139 reads (48%) | called by muse, mutect2, varscan2
- CENPO | c.888G>C p.M296I | Missense Mutation (SNP) | VAF 104/219 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CREBBP | c.3366T>G p.I1122M | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- DPCD | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 66/121 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DUSP1 | c.329G>A p.C110Y | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- G6PC2 | c.176G>A p.W59* | Nonsense Mutation (SNP) | VAF 21/53 reads (40%) | called by muse, mutect2, varscan2
- IQCH | c.715-1G>A p.X239_splice | Splice Site (SNP) | VAF 60/161 reads (37%) | called by muse, mutect2, varscan2
- IRX3 | c.1358G>A p.R453Q | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- ITIH5 | c.77A>G p.H26R | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- KLHL36 | c.1631G>A p.W544* | Nonsense Mutation (SNP) | VAF 47/85 reads (55%) | called by muse, mutect2, varscan2
- LTB | c.163-2A>C p.X55_splice | Splice Site (SNP) | VAF 173/378 reads (46%) | called by muse, varscan2
- MBIP | c.400G>T p.D134Y | Missense Mutation (SNP) | VAF 85/164 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- METTL8 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NT5C1B | c.774G>T p.Q258H (on ENST00000359846 / NM_001199086.2; = p.Q198H on NM_033253.4) | Missense Mutation (SNP) | VAF 69/137 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NXPE1 | c.1276C>A p.L426I (on ENST00000424269; = p.L284I on NM_152315.5) | Missense Mutation (SNP) | VAF 146/307 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PIPOX | c.641G>A p.G214D | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- PLEKHA5 | c.2497G>A p.E833K | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- PLEKHG4B | c.2947G>A p.D983N (on ENST00000283426; = p.D1339N on NM_052909.5) | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- PRDM1 | c.2027T>G p.L676R | Missense Mutation (SNP) | VAF 86/181 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC7A1 | c.370+1G>A p.X124_splice | Splice Site (SNP) | VAF 37/37 reads (100%) | called by muse, mutect2, varscan2
- TRIM41 | c.1631T>C p.L544P | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TTC7B | c.1647del p.N550Tfs*20 | Frame Shift Del (DEL) | VAF 54/114 reads (47%) | called by mutect2, pindel, varscan2
- UBE2J1 | c.27T>G p.S9R | Missense Mutation (SNP) | VAF 61/131 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- USP42 | c.2112G>T p.M704I | Missense Mutation (SNP) | VAF 7/171 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2
- VWA5B1 | c.2341A>T p.T781S | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATP10B | c.1602G>A p.V534= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as rs1338032971; called by muse, mutect2, varscan2
- DDX51 | c.1782G>A p.G594= | Silent (SNP) | VAF 8/214 reads (4%) | called by muse, mutect2
- FNDC3B | c.2019A>G p.Q673= | Silent (SNP) | VAF 47/100 reads (47%) | catalogued as rs775169168; called by muse, mutect2, varscan2
- KIF26A | c.1038G>A p.L346= | Silent (SNP) | VAF 27/51 reads (53%) | catalogued as rs749811229; called by muse, mutect2, varscan2
- LEPROTL1 | c.336T>G p.T112= | Silent (SNP) | VAF 154/327 reads (47%) | called by muse, mutect2, varscan2
- OBP2B | c.30C>T p.L10= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as rs782601503; called by muse, mutect2, varscan2
- PLA2G4A | c.1977T>A p.T659= | Silent (SNP) | VAF 31/122 reads (25%) | called by muse, mutect2, varscan2
- POU6F2 | c.1047G>A p.L349= | Silent (SNP) | VAF 78/148 reads (53%) | catalogued as rs1422111351, COSV101302853; called by muse, varscan2
- PRX | c.2814C>A p.L938= | Silent (SNP) | VAF 16/226 reads (7%) | called by muse, mutect2
- RTL5 | c.372C>T p.P124= | Silent (SNP) | VAF 31/31 reads (100%) | called by muse, mutect2, varscan2
- SOX8 | c.411C>T p.G137= | Silent (SNP) | VAF 22/44 reads (50%) | called by muse, mutect2, varscan2
- SPTBN4 | c.5541G>A p.Q1847= | Silent (SNP) | VAF 60/126 reads (48%) | catalogued as rs772532941; called by muse, mutect2, varscan2
- UBE2I | c.405G>A p.T135= | Silent (SNP) | VAF 111/249 reads (45%) | catalogued as rs542048272; called by muse, mutect2, varscan2
- ADCY2 | c.*2226G>A | 3'UTR (SNP) | VAF 58/113 reads (51%) | called by muse, mutect2, varscan2
- ANKRD34B | c.*780C>A | 3'UTR (SNP) | VAF 34/69 reads (49%) | catalogued as rs886354044; called by muse, mutect2, varscan2
- APBB3 | c.-55T>A | 5'UTR (SNP) | VAF 71/133 reads (53%) | called by muse, mutect2, varscan2
- BEND4 | c.*3688G>A | 3'UTR (SNP) | VAF 40/41 reads (98%) | catalogued as rs1032243188; called by muse, mutect2, varscan2
- BTN3A3 | c.434-98T>C | Intron (SNP) | VAF 16/28 reads (57%) | called by mutect2, varscan2
- C3orf35 | n.1375C>T | RNA (SNP) | VAF 35/70 reads (50%) | called by muse, mutect2, varscan2
- CAND1 | c.*4140G>A | 3'UTR (SNP) | VAF 6/20 reads (30%) | called by mutect2, varscan2
- CDH8 | c.-44dup | 5'UTR (INS) | VAF 22/68 reads (32%) | catalogued as rs746335090; called by mutect2, varscan2
- CENPB | c.*307C>T | 3'UTR (SNP) | VAF 72/130 reads (55%) | called by muse, mutect2, varscan2
- CNKSR3 | c.-456A>C | 5'UTR (SNP) | VAF 5/59 reads (8%) | called by muse, mutect2
- CREB5 | c.*6002C>G | 3'UTR (SNP) | VAF 35/73 reads (48%) | called by muse, mutect2, varscan2
- CYHR1 | c.247-2461G>T | Intron (SNP) | VAF 58/128 reads (45%) | called by muse, varscan2
- DIP2C | c.*3115T>G | 3'UTR (SNP) | VAF 13/21 reads (62%) | called by muse, mutect2, varscan2
- EGLN1 | c.*2000C>T | 3'UTR (SNP) | VAF 68/89 reads (76%) | called by muse, mutect2, varscan2
- EIF2AK2 | c.*5775C>T | 3'UTR (SNP) | VAF 34/68 reads (50%) | called by muse, mutect2, varscan2
- EIF5 | c.*169C>T | 3'UTR (SNP) | VAF 57/100 reads (57%) | called by muse, mutect2, varscan2
- ELK4 | c.*5796A>G | 3'UTR (SNP) | VAF 46/74 reads (62%) | called by muse, varscan2
- FBN2 | c.-577G>T | 5'UTR (SNP) | VAF 35/64 reads (55%) | called by muse, mutect2, varscan2
- FZD4 | c.*3864G>A | 3'UTR (SNP) | VAF 33/70 reads (47%) | called by muse, mutect2, varscan2
- GABRA4 | c.*219C>T | 3'UTR (SNP) | VAF 24/24 reads (100%) | called by muse, mutect2, varscan2
- GABRG2 | chr5:162067655 G>T | 5'Flank (SNP) | VAF 48/83 reads (58%) | called by muse, mutect2, varscan2
- GBP1P1 | n.1580T>C | RNA (SNP) | VAF 41/88 reads (47%) | called by muse, mutect2, varscan2
- GBP5 | c.1363-47C>G | Intron (SNP) | VAF 24/338 reads (7%) | catalogued as rs768565499; called by muse, mutect2
- GCSAML | c.*2636T>C | 3'UTR (SNP) | VAF 33/115 reads (29%) | called by muse, mutect2, varscan2
- GDNF | c.*2908C>T | 3'UTR (SNP) | VAF 30/66 reads (45%) | called by muse, mutect2, varscan2
- GPR84 | c.*10C>T | 3'UTR (SNP) | VAF 18/33 reads (55%) | called by muse, varscan2
- GTF2H1 | c.*743T>G | 3'UTR (SNP) | VAF 17/305 reads (6%) | called by muse, mutect2
- HNRNPCP2 | n.476G>A | RNA (SNP) | VAF 33/63 reads (52%) | called by muse, mutect2, varscan2
- KAT7 | c.*558G>C | 3'UTR (SNP) | VAF 12/180 reads (7%) | called by muse, mutect2
- KIAA1109 | c.*301T>G | 3'UTR (SNP) | VAF 35/81 reads (43%) | called by muse, mutect2, varscan2
- KIAA1143P1 | n.375C>T | RNA (SNP) | VAF 44/89 reads (49%) | called by muse, mutect2, varscan2
- KLF4 | c.6-31C>T | Intron (SNP) | VAF 49/106 reads (46%) | called by muse, mutect2, varscan2
- LIMD1 | c.*174C>T | 3'UTR (SNP) | VAF 40/70 reads (57%) | called by muse, mutect2, varscan2
- LMO7 | c.1307+41C>T | Intron (SNP) | VAF 20/21 reads (95%) | called by muse, mutect2, varscan2
- LNPEP | c.*1271G>T | 3'UTR (SNP) | VAF 44/88 reads (50%) | called by muse, mutect2, varscan2
- LY6K | c.*450C>T | 3'UTR (SNP) | VAF 42/97 reads (43%) | catalogued as rs782321006; called by muse, mutect2, varscan2
- METTL2A | c.*3891G>A | 3'UTR (SNP) | VAF 75/168 reads (45%) | called by muse, mutect2, varscan2
- MIEF2 | c.*971G>T | 3'UTR (SNP) | VAF 25/49 reads (51%) | catalogued as COSV59902238; called by muse, mutect2, varscan2
- MSL3 | c.102+300G>A | Intron (SNP) | VAF 40/40 reads (100%) | catalogued as COSV100384834; called by muse, mutect2, varscan2
- MYO1E | c.-198C>G | 5'UTR (SNP) | VAF 43/78 reads (55%) | called by muse, mutect2, varscan2
- NCAPD3 | c.*2365C>G | 3'UTR (SNP) | VAF 80/198 reads (40%) | called by muse, mutect2, varscan2
- NPAT | c.*1384C>G | 3'UTR (SNP) | VAF 49/49 reads (100%) | called by muse, mutect2, varscan2
- OTOF | c.*349C>T | 3'UTR (SNP) | VAF 17/30 reads (57%) | called by muse, mutect2, varscan2
- PAX6 | c.142-182C>T | Intron (SNP) | VAF 56/103 reads (54%) | called by muse, mutect2, varscan2
- PAX6 | c.10+692T>G | Intron (SNP) | VAF 87/166 reads (52%) | called by muse, mutect2, varscan2
- PHF6 | c.968+1086A>C | Intron (SNP) | VAF 19/54 reads (35%) | called by muse, mutect2, varscan2
- PPP1R3A | c.*706T>G | 3'UTR (SNP) | VAF 5/92 reads (5%) | called by muse, mutect2
- PYGO1 | c.*5617G>C | 3'UTR (SNP) | VAF 57/119 reads (48%) | called by muse, mutect2
- RMND1 | c.*250G>A | 3'UTR (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2
- RNF149 | c.*927C>G | 3'UTR (SNP) | VAF 47/102 reads (46%) | called by muse, mutect2, varscan2
- RNF165 | c.61+31G>A | Intron (SNP) | VAF 61/138 reads (44%) | called by muse, mutect2, varscan2
- SASH1 | c.*280C>T | 3'UTR (SNP) | VAF 39/75 reads (52%) | called by muse, mutect2, varscan2
- SDC2 | c.*2074G>A | 3'UTR (SNP) | VAF 20/43 reads (47%) | called by muse, mutect2, varscan2
- SEC16B | c.1775+255T>C | Intron (SNP) | VAF 41/104 reads (39%) | called by muse, mutect2, varscan2
- SHQ1 | c.*167G>C | 3'UTR (SNP) | VAF 74/151 reads (49%) | called by muse, mutect2, varscan2
- SLC13A1 | c.99+9370T>G | Intron (SNP) | VAF 22/60 reads (37%) | called by muse, mutect2, varscan2
- SLC30A9 | c.*1125dup | 3'UTR (INS) | VAF 14/16 reads (88%) | catalogued as rs1337719119; called by mutect2, varscan2
- SLC31A2 | chr9:113151002 C>T | 5'Flank (SNP) | VAF 5/99 reads (5%) | catalogued as COSV99406849; called by muse, mutect2
- SLC5A2 | c.1022-88G>A | Intron (SNP) | VAF 23/48 reads (48%) | catalogued as rs537526690; called by muse, mutect2, varscan2
- SLCO1A2 | c.*2928G>A | 3'UTR (SNP) | VAF 38/80 reads (48%) | called by muse, mutect2, varscan2
- SMIM4 | c.-116G>C | 5'UTR (SNP) | VAF 72/172 reads (42%) | catalogued as rs1032427066; called by muse, mutect2, varscan2
- SNX13 | c.2626+646A>T | Intron (SNP) | VAF 23/56 reads (41%) | called by muse, mutect2, varscan2
- STRAP | c.-284G>A | 5'UTR (SNP) | VAF 50/119 reads (42%) | called by muse, mutect2, varscan2
- STX7 | c.*1754T>C | 3'UTR (SNP) | VAF 38/66 reads (58%) | called by muse, varscan2
- TAF5L | c.*282C>T | 3'UTR (SNP) | VAF 140/388 reads (36%) | catalogued as rs987730544; called by muse, mutect2
- TENT5A | c.*1236C>T | 3'UTR (SNP) | VAF 18/41 reads (44%) | called by muse, mutect2, varscan2
- TMEM167A | c.*3360T>G | 3'UTR (SNP) | VAF 98/213 reads (46%) | called by muse, mutect2, varscan2
- TMEM201 | c.1160+167G>A | Intron (SNP) | VAF 63/125 reads (50%) | catalogued as rs985996018; called by muse, mutect2, varscan2
- TOMM70 | c.*1387C>T | 3'UTR (SNP) | VAF 48/97 reads (49%) | catalogued as rs758849185; called by muse, mutect2, varscan2
- TPO | c.*474G>T | 3'UTR (SNP) | VAF 6/148 reads (4%) | called by muse, mutect2
- UNC5A | c.*14C>T | 3'UTR (SNP) | VAF 76/149 reads (51%) | catalogued as rs373776635, COSV99458601; called by muse, mutect2, varscan2
- UTP25 | c.*518C>T | 3'UTR (SNP) | VAF 30/90 reads (33%) | called by muse, mutect2, varscan2
- ZIC1 | c.*1573C>T | 3'UTR (SNP) | VAF 33/71 reads (46%) | called by muse, mutect2, varscan2
